Somatic mutation profile of tumor specimen MMRF_2021_1_BM_CD138pos (aliquot MMRF_2021_1_BM_CD138pos_T1_KHS5U_L08847) from MMRF case MMRF_2021, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.3 years (24,206 days).
Specimen MMRF_2021_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 001dc356-1dc9-478a-a1ce-244631af095b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2021_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2021_1_PB_Whole_C2_KHS5U_L08848; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/290f3141-1438-491a-bde2-da02dc0acc8f

The open-access MAF lists 70 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, 3'UTR 19, Intron 8, Silent 7, 5'UTR 6, 3'Flank 3, Splice Site 2, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATF4 | c.226+2T>A p.X76_splice | Splice Site (SNP) | VAF 48/112 reads (43%) | catalogued as COSV57480863; called by muse, mutect2, varscan2
- DIP2C | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764285130, COSV55154011; called by muse, mutect2, varscan2
- DRC3 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs756240634, COSV58266864; called by muse, mutect2, varscan2
- IGHV2-70 | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs373048671; called by muse, varscan2
- IRF8 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs945535357, COSV99236176; called by muse, mutect2
- MROH1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs765456584; called by muse, mutect2, varscan2
- PPP2R2B | c.785C>A p.T262N (on ENST00000394409; = p.T328N on NM_181674.2) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs1175107881, COSV100354033; called by mutect2, varscan2
- ST6GALNAC1 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 28/65 reads (43%) | PolyPhen probably damaging (0.951); catalogued as rs766654048, COSV50074321; called by muse, mutect2, varscan2
- TNRC18 | c.4457G>A p.R1486Q | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.429); catalogued as rs570365021, COSV68166613; called by muse, mutect2, varscan2
- BCL2L13 | c.302A>G p.E101G | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL5A1 | c.5310C>A p.N1770K | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DEF6 | c.47C>G p.T16S | Missense Mutation (SNP) | VAF 118/265 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- EXOC5 | c.2077C>A p.Q693K | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- EYS | c.4268C>T p.P1423L | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMD6 | c.1219G>A p.G407R (on ENST00000344768 / NM_001267046.2; = p.G399R on NM_152330.4) | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- IMPG2 | c.2725A>G p.N909D | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNAB2 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MYH2 | c.2128A>G p.I710V | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- NOL6 | c.3160C>A p.P1054T | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SAMD3 | c.1023+2T>C p.X341_splice | Splice Site (SNP) | VAF 4/97 reads (4%) | called by muse, mutect2
- SLITRK3 | c.392A>T p.Y131F | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- TASOR | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- TASOR | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- YTHDC1 | c.1651A>T p.I551F (on ENST00000344157 / NM_001031732.4; = p.I533F on NM_133370.4) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- ZNFX1 | c.5567T>A p.V1856E | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- EPHA6 | c.2397G>A p.P799= (on ENST00000389672 / NM_001080448.3; = p.P191= on NM_173655.4) | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs751500179, COSV101064910; called by muse, mutect2, varscan2
- NACAD | c.4494A>T p.A1498= | Silent (SNP) | VAF 15/183 reads (8%) | called by muse, mutect2
- PKHD1 | c.3450T>C p.A1150= | Silent (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- SAMM50 | c.390C>A p.G130= | Silent (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.1425T>C p.D475= | Silent (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- SSTR1 | c.996C>A p.R332= | Silent (SNP) | VAF 91/181 reads (50%) | called by muse, mutect2, varscan2
- XPNPEP3 | c.498G>A p.P166= | Silent (SNP) | VAF 77/150 reads (51%) | catalogued as rs775368300; called by muse, mutect2, varscan2
- ADH4 | c.*75G>A | 3'UTR (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- AP000769.5 | chr11:65500549 T>C | 5'Flank (SNP) | VAF 51/126 reads (40%) | called by muse, mutect2, varscan2
- CHM | c.*3002A>G | 3'UTR (SNP) | VAF 34/35 reads (97%) | called by muse, mutect2, varscan2
- CLU | c.*824A>G | 3'UTR (SNP) | VAF 5/106 reads (5%) | called by muse, mutect2
- CRP | c.*611G>T | 3'UTR (SNP) | VAF 35/88 reads (40%) | catalogued as rs375902861; called by muse, mutect2, varscan2
- CRTC3 | c.352-3297G>A | Intron (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- CXCL12 | c.*1346C>A | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- DLGAP2 | c.*5269A>T | 3'UTR (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2
- DYNC2LI1 | c.993+29A>T | Intron (SNP) | VAF 57/153 reads (37%) | called by muse, mutect2, varscan2
- EAF1 | c.761-42del | Intron (DEL) | VAF 32/80 reads (40%) | called by mutect2, pindel, varscan2
- EIF3E | c.1300-28G>A | Intron (SNP) | VAF 74/165 reads (45%) | catalogued as rs918251652; called by muse, mutect2, varscan2
- ETV3 | c.*235A>G | 3'UTR (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- FBXO25 | c.1014+140G>A | Intron (SNP) | VAF 23/39 reads (59%) | called by muse, mutect2, varscan2
- GAS2L3 | chr12:100624996 G>C | 3'Flank (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- ITPRIP | c.*1440C>G | 3'UTR (SNP) | VAF 56/124 reads (45%) | catalogued as rs1483423413; called by muse, mutect2, varscan2
- LRP1B | c.*310T>A | 3'UTR (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- MAP1A | c.-6G>A | 5'UTR (SNP) | VAF 19/53 reads (36%) | catalogued as rs1343566189; called by muse, mutect2, varscan2
- MTPN | c.-110C>T | 5'UTR (SNP) | VAF 54/107 reads (50%) | catalogued as rs1339227393; called by muse, mutect2
- NAV2 | chr11:20121404 T>C | 3'Flank (SNP) | VAF 46/95 reads (48%) | called by muse, mutect2, varscan2
- OPRK1 | c.-117C>T | 5'UTR (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- PCMTD1 | c.*1932_*1933insGTT | 3'UTR (INS) | VAF 15/60 reads (25%) | called by mutect2, varscan2
- PNPLA7 | c.3682-91G>T | Intron (SNP) | VAF 18/42 reads (43%) | catalogued as rs969090115; called by muse, mutect2, varscan2
- PRPF40B | c.229-192C>G | Intron (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- PRSS23 | c.*426G>T | 3'UTR (SNP) | VAF 58/110 reads (53%) | called by muse, mutect2, varscan2
- PSMC3 | c.75+17C>T | Intron (SNP) | VAF 27/62 reads (44%) | catalogued as rs1321128793; called by muse, mutect2, varscan2
- QSOX1 | c.*2146C>T | 3'UTR (SNP) | VAF 74/162 reads (46%) | catalogued as rs1274344033; called by muse, mutect2, varscan2
- RNF128 | c.-42T>C | 5'UTR (SNP) | VAF 35/37 reads (95%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*3251del | 3'UTR (DEL) | VAF 19/42 reads (45%) | catalogued as rs911913545; called by mutect2, pindel*
- SCEL | c.*515C>A | 3'UTR (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- SCN4B | c.*1838C>A | 3'UTR (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- SERPINI1 | c.*121A>T | 3'UTR (SNP) | VAF 46/127 reads (36%) | called by muse, mutect2, varscan2
- SIM1 | chr6:100388365 C>A | 3'Flank (SNP) | VAF 22/42 reads (52%) | catalogued as rs932740472; called by muse, mutect2, varscan2
- TLR9 | c.-81C>T | 5'UTR (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- TMEM132D | c.*1931T>C | 3'UTR (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- TMEM99 | n.908T>C | RNA (SNP) | VAF 44/96 reads (46%) | called by muse, mutect2, varscan2
- USH2A | c.*117T>C | 3'UTR (SNP) | VAF 40/114 reads (35%) | called by muse, mutect2, varscan2
- VAMP1 | c.-112C>T | 5'UTR (SNP) | VAF 45/77 reads (58%) | catalogued as rs1424364277, COSV100655597; called by muse, mutect2, varscan2
- ZNF260 | c.*618C>G | 3'UTR (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
